Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6651, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6651-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Subtotal colectomy
- B. Small bowel mass
- C. Appendectomy

CLINICAL NOTES

PRE-OP DIAGNOSIS: Transverse colon cancer

FROZEN SECTION DIAGNOSIS

- B. Serosal fibrosis, no tumor seen [REDACTED] on, further evaluation on permanent sections. [REDACTED]

GROSS DESCRIPTION

A. Received fresh in a container labeled "colon" is a segment of colon 23 cm long. The specimen is received open at both ends, which are arbitrarily inked blue and black. The serosal surface is tan-pink and glistening. There is abundant attached yellow adipose tissue. There is also abundant omentum present, 42 x 5 x 3 cm in greatest dimensions. The omentum is serially sectioned, and there are no focal lesions. The segment of bowel is opened. It averages 6.5 cm in circumference. 5.5 cm from the black-inked end of the specimen, there is a 5.5 x 5 x 3.8 cm tumor mass. On cut surface, this tumor grossly invades into, and apparently through, the muscularis propria, into surrounding soft tissues. Although extending near to the serosal surface, tumor does not appear to reach the serosal surface, and is not near the radial margin. The surface deep to the tumor is inked. 3.5 cm from the blue-inked margin is a separate 3.5 x 3.3 x 2.7 cm polypoid lesion. There is some black tattooing in this region. On cut surface, the polypoid lesion is exophytic, without definite gross invasion into the bowel wall. The specimen away from the lesions has a tan-pink glistening mucosa and tan wall. The adipose tissue is dissected, and multiple tan lymph nodes are identified. RS-22, following fixation.

BLOCK SUMMARY: A1,A2 - omentum; A3 - proximal and distal resection margins; A4-A7 - invasive tumor mass, with one lymph node also included in block A7; A8-A16 - entire polypoid lesion; A17-A22 - lymph nodes.

B. Received fresh in a container labeled "B - small bowel mass" is a portion of tan tissue with mucosa along one surface, 3 x 2 cm, and 0.3 cm deep, compatible with small bowel. On the serosal surface there is a tan-white plaque-like area, 0.8 x 0.5 x 0.1 cm. A section is submitted for frozen section, including the plaque-like area, and the remainder of the specimen is entirely submitted for permanent sections in three additional blocks.

C. Received in formalin in a container labeled "appendix" is a 5.5 cm long x 0.7 cm in diameter appendix. It is grossly unremarkable, with a tan-pink glistening serosal surface, wall, and tan mucosa. There are no focal lesions. AS-1.

[REDACTED]

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

The following template summarizes the findings in this case:

Histologic type: Adenocarcinoma of the colon in part A, present in the lesion submitted in blocks A4-A7.

Histologic grade: Moderately differentiated

Primary tumor (pT): pT3. Adenocarcinoma invades through the full thickness of the muscularis propria into surrounding adipose tissue.

Proximal margin: Negative

Distal margin: Negative

Circumferential (radial) margin: Negative

Distance of tumor from closest margin: See gross description

Vascular invasion: Not definitively identified

Regional lymph nodes (pN): pN1b. There is metastatic adenocarcinoma in two of thirty-three (2/33) lymph nodes. One of the positive lymph nodes is the lymph node immediately subjacent to the tumor submitted in block A7.

Non-lymph node pericolic tumor: Not identified

Distant metastasis (pM): pMX

Other findings: The separate polypoid lesion in part A is a tubulovillous adenoma with focal severe dysplasia. Part A is also notable for [REDACTED]. Part B has serosal fibrosis, without tumor seen. In part C, appendix is without specific diagnostic abnormalities, with luminal obliteration.

Note: This case has been reviewed in Intradepartmental Consultation, with concurrence with the interpretation.

5,4,1,14

DIAGNOSIS

- A. Colon, subtotal excision
- Moderately differentiated adenocarcinoma, invading through the full thickness of the muscularis propria and into the surrounding adipose tissue (pT3, see microscopic description).
- Separate tubulovillous adenoma, with focal severe dysplasia.
- Margins negative for malignancy.
- Metastatic adenocarcinoma in two of thirty-three (2/33) lymph nodes.
- B. Tissue, small bowel, excision
- Serosal fibrosis, no tumor seen.
- C. Appendix, excision
- Luminal obliteration, without specific diagnostic abnormalities.
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 944132da-1f72-4c24-bd13-af64d6cf8a83 (TCGA-A6-6651.93F31F79-8BBE-411C-9CCC-C7EA0A4D4937.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).